Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AACQ, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AACQ-01A (Primary Tumor).

[page 1 of 2]
CLINICAL DIAGNOSIS: HCC

Specimen : lt. lobe of liver

Gross Photo : 1

GROSS:

Procedure: Laparoscopic assisted left lobectomy

Specimen:

Liver: 13.0 x 10.0 x 4.5 cm, fresh (cirrhotic liver)

Tumor location: Left lobe

Tumor number: Two

Tumor size: 3.4 x 2.9 x 1.9 cm, 0.9 x 0.6 x 0.6 cm

Satellite nodule: Absent

Gross type: Expanding nodular

Tumor necrosis: Absent

Hemorrhage/peliosis: Absent

Portal vein invasion: Absent

Bile duct invasion: Absent

ICD O.3
Carcinoma, hepatocellular NOS
8170/3
Site: Liver C22.0
JN 5/19/14

Gross photo present.

Blocks

T1-3, expanding nodular mass x 3

T4, another seperated mass x 1

L, remaining liver parenchyme x 1

RM, resection margin of liver x 1

MICROSCOPIC:

Tumor type:

Hepatocellular carcinoma

Differentiation

The worst differentiation III

The major differentiation II

Histologic type:

pseudoglandular, trabecular, solid and micropapillary

Cell type: Hepatic

Fatty change: Steatosis, mild

Fibrous capsule formation: Absent

Capsular infiltration: Absent

Septum formation: Absent

Surgical resection margin invasion: Free from tumor

[page 2 of 2]
Serosal invasion: Absent
Portal vein invasion: Absent
Bile duct invasion: Absent
Hepatic vein invasion: Absent
Hepatic artery invasion: Absent
Microvessel invasion: Absent
Multicentric occurrence: Present

Non-tumor liver pathology
Cirrhosis, mixed, HBV-associated
Dysplastic nodule: Absent
Ductal epithelial dysplasia: Absent
Other liver diseases: Absent

SPECIAL STAIN: Trichrome (+, consistent with liver cirrhosis)

NOT reported. Gross:

Peritoneal fluid, smear, atypical cells

liver, needle, chronic persistent hepatitis

Liver, needle biopsy, Cirrhosis

Skin, face, punch biopsy, granulomatous inflammation

Liver, ectomy, hepatocellular carcinoma
T56000, P10, M81703

DIAGNOSIS:

Liver, left, laparoscopic assisted left lobectomy:
Hepatocellular carcinoma, moderately differentiated

Suggestion :

Source: NCI Genomic Data Commons file 7fa70d40-72f6-46dc-957a-2a6c6459a575 (TCGA-DD-AACQ.3BBE2BEA-D346-4EA8-82CB-9305EC49A331.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).